Somatic mutation profile of tumor specimen MP2PRT-PANUHD-TMP1-A (aliquot MP2PRT-PANUHD-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANUHD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (959 days).
Specimen MP2PRT-PANUHD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e39aac1b-39df-4e98-80d4-3c525d0ccbe2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANUHD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANUHD-NB1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/735cc744-bbd6-4960-998a-88bba3c39935

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLNA | c.1769T>G p.V590G | Missense Mutation (SNP) | VAF 276/407 reads (68%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.568); catalogued as rs1351197959; called by muse, mutect2, varscan2
- H2AC6 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 42/514 reads (8%) | catalogued as COSV100020137; called by muse, mutect2
- OPN4 | c.1241C>T p.S414L | Missense Mutation (SNP) | VAF 90/347 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs926293228; called by muse, mutect2, varscan2
- RSKR | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 164/389 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.026); catalogued as rs1046342133; called by muse, mutect2, varscan2
- EGFR | c.3247G>A p.D1083N | Missense Mutation (SNP) | VAF 56/822 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.069); called by muse, mutect2
- ARHGAP27 | c.1131C>T p.P377= (on ENST00000428638 / NM_001282290.1; = p.P36= on NM_199282.3) | Silent (SNP) | VAF 74/829 reads (9%) | called by muse, mutect2
- CEP83 | c.441A>C p.V147= | Silent (SNP) | VAF 71/176 reads (40%) | called by muse, mutect2, varscan2
- SLC16A11 | c.945C>T p.F315= (on ENST00000308009; = p.F291= on NM_153357.3) | Silent (SNP) | VAF 82/1110 reads (7%) | called by muse, mutect2
- TSPAN5 | c.504C>T p.F168= | Silent (SNP) | VAF 26/413 reads (6%) | catalogued as rs545750449; called by muse, mutect2
